Gene-level copy-number profile of tumor specimen TCGA-VQ-A8DL-01A from TCGA case TCGA-VQ-A8DL, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 69.3 years (25,299 days).
Specimen TCGA-VQ-A8DL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.c4915ca1-91ad-4c91-a3dc-43d2b1115293.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8DL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a8ccc312-9e08-4027-a9ad-728b8a52880e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 83; copy number 1: 13,094; copy number 2: 41,056; copy number 3: 2,314; copy number 4: 3,043; copy number 5: 9; copy number 7: 147; copy number 21: 59; copy number 22: 1; copy number 29: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8DL-01A-11D-A363-01): tumor purity 0.49, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 83 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:183,607,442–189,012,746, 48 genes (within-gene range 0–1): CACYBPP2, AC093639.3, AC093639.1, AC093639.2, AC096555.1, AC020584.1, MIR548AE1, AC096667.1, ZNF804A, RPL23AP33, AC009315.1, ELF2P4, FSIP2-AS1, U8, FSIP2-AS2, FSIP2, AC097500.1, RPL21P32, LINC01473, AC104058.1, RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV, AC017101.1, FAM171B, ZSWIM2, IMPDH1P7, AC007319.1, RN7SKP42, RNU6-989P, CALCRL, GAPDHP59, TFPI, LINC01090, ST13P2, AC104131.1, RNA5SP114, GULP1, MIR561, AC092598.1, DIRC1, COL3A1, MIR1245A, MIR1245B, MIR3606.
- chr6:1,601,654–1,613,897, 2 genes: FOXCUT, FOXC1.
- chr14:66,012,830–66,013,789, 1 gene: YBX1P1.
- chr15:25,865,295–26,939,539, 12 genes (within-gene range 0–1): AC016266.1, LINC02346, AC044913.2, AC044913.1, AC100836.1, LINC00929, AC012060.1, LINC02248, AC009878.2, GABRB3, AC009878.1, AC011196.1.
- chr21:41,679,181–42,366,535, 20 genes: LINC00111, LINC00479, LINC00112, RIPK4, AP001615.1, MIR6814, PRDM15, AP001619.2, AP001619.1, AP001619.3, C2CD2, ZBTB21, ZNF295-AS1, UMODL1, UMODL1-AS1, ABCG1, RNA5SP492, TFF3, TFF2, TFF1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 219 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,938,929–176,867,838, 9 genes, copy number 5: AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209.
- chr17:38,195,703–41,836,260, 210 genes, copy number 7–29 (within-gene range 1–29) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,064. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
